Somatic mutation profile of tumor specimen TCGA-97-A4M3-01A (aliquot TCGA-97-A4M3-01A-11D-A24P-08) from TCGA case TCGA-97-A4M3, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.5 years (25,384 days).
Specimen TCGA-97-A4M3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5ce47ea-a60d-4981-8cd7-6d6e13b08033.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-A4M3-10A (Blood Derived Normal), aliquot TCGA-97-A4M3-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0f11989-c592-4d6b-a1ce-58f2a93cd7f0

The open-access MAF lists 224 somatic variants for this specimen: 180 protein-altering or splice-affecting, 35 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 35, Nonsense Mutation 8, Splice Site 6, Intron 5, Frame Shift Del 4, RNA 3, Splice Region 2, Frame Shift Ins 1, Nonstop Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 37/58 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SOS1 | c.697A>T p.N233Y | Missense Mutation (SNP) | VAF 39/55 reads (71%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen possibly damaging (0.671); catalogued as rs1057519963, COSV67673722; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.180del p.Y60* | Frame Shift Del (DEL) | VAF 24/49 reads (49%) | catalogued as rs1555735008, CD064644, CM981863, CM991149, COSV58820509, COSV58821737, COSV58821906; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AAR2 | c.821G>T p.W274L | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57924907; called by muse, mutect2, varscan2
- AAR2 | c.822G>T p.W274C | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100299180; called by muse, mutect2, varscan2
- ABCC11 | c.1628G>T p.C543F | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV100750616; called by muse, mutect2, varscan2
- ACVR1C | c.1172T>A p.I391N | Missense Mutation (SNP) | VAF 83/160 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99694460; called by muse, mutect2, varscan2
- ADAM17 | c.2332G>C p.E778Q | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.115); catalogued as COSV60397345; called by muse, mutect2, varscan2
- ADAMTS2 | c.1061C>A p.T354K | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.822); catalogued as COSV99201140; called by muse, mutect2, varscan2
- ADGRG7 | c.1031G>A p.S344N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV99840700; called by muse, mutect2, varscan2
- ADGRV1 | c.13474A>G p.T4492A | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV101315636; called by muse, mutect2
- ADIPOQ | c.13G>T p.G5* | Nonsense Mutation (SNP) | VAF 24/45 reads (53%) | catalogued as COSV100292116; called by muse, varscan2
- AIPL1 | c.1124C>A p.P375H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV100005991; called by muse, mutect2, varscan2
- ALDH1A1 | c.1151C>A p.P384H | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52788904; called by muse, mutect2
- AMER1 | c.2252C>A p.P751H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV100365589; called by muse, mutect2, varscan2
- ANGPTL1 | c.697C>A p.L233M | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.758); catalogued as COSV52366688, COSV99328043; called by muse, mutect2, varscan2
- ANKRD30A | c.3531G>T p.M1177I (on ENST00000611781; = p.M1121I on NM_052997.2) | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV100653123; called by muse, mutect2
- ARHGAP32 | c.5503G>A p.E1835K (on ENST00000310343 / NM_001378025.1; = p.E1486K on NM_014715.4) | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.664); catalogued as rs1444742246, COSV100087246; called by muse, mutect2, varscan2
- ARHGAP35 | c.992A>T p.E331V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV101350801; called by muse, mutect2, varscan2
- ARHGAP35 | c.1889G>T p.G630V | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101350802; called by muse, mutect2, varscan2
- ARHGEF40 | c.2461G>T p.E821* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as COSV100070150; called by muse, mutect2, varscan2
- ARID3A | c.1541A>T p.N514I | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99708296, COSV99708587; called by muse, mutect2, varscan2
- AS3MT | c.404A>G p.Y135C | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.304); catalogued as COSV100185617; called by muse, mutect2
- ASTN1 | c.1711G>T p.V571L | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as COSV99920871; called by muse, mutect2, varscan2
- ASXL3 | c.2545C>A p.P849T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV99323946; called by muse, mutect2, varscan2
- ASXL3 | c.3286A>G p.T1096A | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99323948; called by muse, mutect2, varscan2
- ATP7B | c.2137T>C p.Y713H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.318); catalogued as COSV99666185; called by muse, mutect2, varscan2
- BET1 | c.19G>T p.G7C | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99747210; called by muse, mutect2, varscan2
- BNC1 | c.680C>A p.P227H | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV100597000; called by muse, mutect2, varscan2
- BTNL3 | c.1295T>C p.L432P | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs1423275138, COSV100732186; called by muse, mutect2, varscan2
- C6 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.859); catalogued as COSV99666752; called by muse, mutect2, varscan2
- CBFA2T3 | c.1655C>A p.S552Y | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99241300; called by muse, mutect2, varscan2
- CCDC88A | c.62G>A p.W21* | Nonsense Mutation (SNP) | VAF 14/94 reads (15%) | catalogued as COSV99709967; called by muse, varscan2
- CDH5 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100439091; called by muse, mutect2, varscan2
- CEP55 | c.372G>T p.E124D | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as rs1487462961, COSV101016899; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.432C>G p.D144E | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.381); catalogued as COSV99267258; called by muse, mutect2, varscan2
- CFAP74 | c.4490C>G p.A1497G | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs550996059; called by muse, mutect2, varscan2
- CHST7 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV99332819; called by muse, mutect2, varscan2
- CLPS | c.338G>C p.*113Sext*42 | Nonstop Mutation (SNP) | VAF 20/125 reads (16%) | catalogued as COSV99463606, COSV99463707; called by muse, mutect2, varscan2
- COL11A1 | c.489-1G>C p.X163_splice | Splice Site (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100615540; called by muse, mutect2, varscan2
- COL21A1 | c.2309G>T p.G770V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55168273, COSV99777916; called by muse, mutect2, varscan2
- COMMD4 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs1211689053, COSV99143115; called by muse, mutect2, varscan2
- COPB1 | c.2844G>T p.Q948H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99999355; called by muse, mutect2, varscan2
- CS | c.1060G>C p.D354H | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100369925; called by muse, mutect2, varscan2
- CYP3A7 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV100312593; called by muse, mutect2, varscan2
- DCUN1D4 | c.99C>T p.N33= | Splice Region (SNP) | VAF 27/78 reads (35%) | catalogued as rs1250463987, COSV100584417; called by muse, mutect2, varscan2
- DENND2A | c.2884C>T p.R962W | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs372102093; called by muse, mutect2, varscan2
- DHFR2 | c.232A>G p.R78G | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs372488392, COSV100113166; called by muse, mutect2
- DMGDH | c.1210G>T p.A404S | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.385); catalogued as rs760553323, COSV99668639; called by muse, mutect2, varscan2
- DMXL1 | c.3986A>C p.Q1329P | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100223546; called by muse, mutect2, varscan2
- DPH2 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 112/252 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV52545583, COSV99356303; called by muse, mutect2, varscan2
- DPP10 | c.1507C>A p.L503I | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV100060851; called by muse, mutect2, varscan2
- DPY19L3 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.32); PolyPhen probably damaging (1); catalogued as rs1188106927, COSV100639138, COSV60475728; called by muse, mutect2, varscan2
- DSG1 | c.1594C>A p.P532T | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99935710; called by muse, mutect2, varscan2
- DSG4 | c.2758C>A p.P920T | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100355567; called by muse, mutect2, varscan2
- ELF4 | c.752G>T p.W251L | Missense Mutation (SNP) | VAF 79/240 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100257236; called by muse, mutect2, varscan2
- EOMES | c.1738T>C p.S580P | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99841800; called by muse, mutect2, varscan2
- FAM199X | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101534159, COSV101534170; called by muse, mutect2, varscan2
- FBXO30 | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99395067; called by muse, mutect2, varscan2
- FGD2 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.07); catalogued as COSV99235969; called by muse, mutect2, varscan2
- FILIP1 | c.2755G>T p.E919* | Nonsense Mutation (SNP) | VAF 67/183 reads (37%) | catalogued as COSV52727424, COSV99385275; called by muse, mutect2, varscan2
- GADL1 | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759593970, COSV99244035; called by muse, mutect2, varscan2
- GALNT16 | c.1271+1G>T p.X424_splice | Splice Site (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100545703; called by muse, mutect2, varscan2
- GFPT1 | c.1423G>A p.E475K (on ENST00000357308 / NM_001244710.2; = p.E457K on NM_002056.4) | Missense Mutation (SNP) | VAF 75/304 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.386); catalogued as COSV61946597; called by muse, mutect2, varscan2
- GIMAP1 | c.228C>G p.C76W | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100212005; called by muse, mutect2, varscan2
- GLG1 | c.2053-2A>G p.X685_splice | Splice Site (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99215484; called by muse, mutect2
- GLI2 | c.4039G>T p.A1347S (on ENST00000361492 / NM_001374353.1; = p.A1364S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs878895919, COSV100082652, COSV58044277; called by muse, mutect2, varscan2
- GPR132 | c.319C>A p.R107S | Missense Mutation (SNP) | VAF 63/209 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.471); catalogued as COSV100317482; called by muse, mutect2, varscan2
- GPR26 | c.438G>T p.W146C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99500795; called by muse, mutect2, varscan2
- GPRIN1 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1048027500, COSV99991226; called by muse, mutect2, varscan2
- H1-3 | c.563A>G p.K188R | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs773167542, COSV99768659; called by muse, mutect2, varscan2
- HCRTR1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.831); catalogued as COSV101036151; called by muse, mutect2, varscan2
- IL7R | c.651G>T p.W217C | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM983406, COSV100286028, COSV57409072; called by muse, mutect2, varscan2
- ITGA11 | c.438C>G p.F146L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV100241168; called by muse, mutect2, varscan2
- ITGA8 | c.2662C>A p.P888T | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.171); catalogued as COSV100959007, COSV65237271; called by muse, mutect2, varscan2
- ITGAD | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV101210387; called by muse, mutect2, varscan2
- JMJD1C | c.2237G>A p.R746K | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.22); catalogued as COSV101232273, COSV101232468; called by muse, mutect2, varscan2
- KEAP1 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV50339578; called by muse, mutect2, varscan2
- KERA | c.50C>A p.T17N | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV99899357; called by muse, mutect2, varscan2
- KIAA0100 | c.637A>T p.S213C | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV101197249; called by muse, mutect2, varscan2
- KRT28 | c.649C>A p.L217M | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100137430; called by muse, mutect2, varscan2
- LAMA4 | c.3116A>T p.K1039M (on ENST00000230538 / NM_001105206.3; = p.K1032M on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100037883; called by muse, mutect2
- LAMB1 | c.3718G>A p.A1240T | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV99740217; called by muse, mutect2, varscan2
- LPA | c.2509A>T p.T837S | Missense Mutation (SNP) | VAF 15/271 reads (6%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.931); catalogued as COSV100306383; called by muse, mutect2
- LRP1B | c.3248G>T p.S1083I | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV101254201; called by muse, mutect2, varscan2
- LRRC7 | c.688G>A p.G230S (on ENST00000651989 / NM_001370785.2; = p.G197S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.215); catalogued as COSV99225347; called by muse, mutect2, varscan2
- LRRC7 | c.4258G>T p.G1420W (on ENST00000651989 / NM_001370785.2; = p.G1340W on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99225350; called by muse, mutect2, varscan2
- MAGIX | c.445A>T p.T149S | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV100891851; called by muse, mutect2, varscan2
- MAP7D1 | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs1274861080, COSV100294299; called by muse, mutect2, varscan2
- MARK2 | c.981del p.R328Gfs*4 | Frame Shift Del (DEL) | VAF 52/171 reads (30%) | catalogued as COSV59280888; called by mutect2, pindel, varscan2
- MBL2 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as COSV100906283; called by muse, mutect2, varscan2
- MKI67 | c.7672G>T p.D2558Y | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100896327; called by muse, mutect2, varscan2
- MTA2 | c.875A>T p.Q292L | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99604108; called by muse, mutect2, varscan2
- MTOR | c.1676A>T p.K559M | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV100815837; called by muse, mutect2
- MUC16 | c.23589C>G p.I7863M | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.266); catalogued as COSV101198822, COSV67482861, COSV67498998; called by muse, mutect2, varscan2
- MYOM1 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99865793; called by muse, mutect2, varscan2
- NALCN | c.4562G>T p.R1521M | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99213640; called by muse, mutect2, varscan2
- NBAS | c.1086A>G p.P362= | Splice Region (SNP) | VAF 16/30 reads (53%) | catalogued as COSV99868033; called by muse, mutect2, varscan2
- NCAPD3 | c.2128A>T p.T710S | Missense Mutation (SNP) | VAF 42/67 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV101599339; called by muse, mutect2, varscan2
- NCL | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.794); catalogued as rs753488545, COSV59544882; called by muse, mutect2, varscan2
- NES | c.3598C>T p.P1200S | Missense Mutation (SNP) | VAF 89/139 reads (64%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs1373731571, COSV63962005; called by muse, mutect2, varscan2
- NLGN4X | c.689C>A p.A230E | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99320532; called by muse, mutect2, varscan2
- OFD1 | c.1088T>C p.I363T | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100406790; called by muse, mutect2, varscan2
- OR2T2 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs766007158, COSV61619558; called by muse, mutect2, varscan2
- OR8H3 | c.492C>A p.S164R | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.151); catalogued as COSV57909620; called by muse, mutect2, varscan2
- OSR1 | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 62/91 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV55345017, COSV55346288; called by muse, mutect2, varscan2
- OXCT1 | c.1225G>T p.D409Y | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99541862; called by muse, mutect2, varscan2
- P2RX1 | c.587C>A p.P196Q | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99844634; called by muse, mutect2, varscan2
- P2RY10 | c.192C>A p.S64R | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV99409004; called by muse, mutect2, varscan2
- PAK5 | c.1793C>A p.P598Q | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.906); catalogued as COSV100781197; called by muse, mutect2, varscan2
- PCDHA11 | c.457C>G p.P153A | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.517); catalogued as COSV100248789, COSV56485236; called by muse, mutect2, varscan2
- PCDHB5 | c.2360C>A p.A787D | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); catalogued as COSV99167738; called by muse, mutect2, varscan2
- PCDHGB4 | c.1747G>T p.G583C | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99533648; called by muse, mutect2, varscan2
- PCNX3 | c.2586C>A p.F862L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV100856144; called by muse, mutect2, varscan2
- PDE11A | c.2721G>C p.E907D | Missense Mutation (SNP) | VAF 96/225 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99611264; called by muse, mutect2, varscan2
- PHF6 | c.565G>T p.E189* (on ENST00000332070 / NM_032458.3; = p.E190* on NM_032335.3) | Nonsense Mutation (SNP) | VAF 63/200 reads (32%) | catalogued as COSV100136307, COSV59706437; called by muse, mutect2, varscan2
- PKHD1 | c.6050C>T p.S2017F | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.037); catalogued as COSV100581884; called by muse, mutect2, varscan2
- PLAT | c.1099C>A p.H367N | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as COSV99535050; called by muse, mutect2
- PLCG2 | c.236C>A p.S79Y | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100842125, COSV63867834; called by muse, mutect2, varscan2
- PPP1R10 | c.1823A>G p.D608G | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100919773; called by muse, mutect2, varscan2
- PRMT9 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100482045; called by muse, mutect2, varscan2
- PRPF8 | c.3583C>T p.R1195C | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1343543361, COSV59260424; called by muse, mutect2, varscan2
- PRUNE2 | c.5911G>T p.D1971Y | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV100944320; called by muse, mutect2
- PRUNE2 | c.4240G>A p.D1414N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV100944322; called by muse, mutect2, varscan2
- PTGER4 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100201477; called by muse, mutect2, varscan2
- RAB11FIP3 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51931636, COSV99239994; called by muse, mutect2, varscan2
- RAPH1 | c.2589G>C p.K863N | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.521); catalogued as COSV99863541; called by muse, mutect2, varscan2
- RB1CC1 | c.4565C>G p.T1522S | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.806); catalogued as COSV50245016; called by muse, mutect2, varscan2
- RIMBP2 | c.1493G>T p.G498V | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99898771; called by muse, mutect2, varscan2
- RPS6KA6 | c.1946G>T p.W649L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99424359; called by muse, mutect2
- RPS6KA6 | c.1945T>C p.W649R | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99424360; called by muse, mutect2
- RTN4R | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99244886, COSV99244904; called by muse, mutect2, varscan2
- SEC14L1 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101170910; called by muse, mutect2, varscan2
- SEC24B | c.1946G>T p.G649V | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV99493086; called by muse, mutect2, varscan2
- SIRT6 | c.786G>C p.M262I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as COSV99313963; called by muse, mutect2, varscan2
- SLC14A2 | c.2183C>G p.A728G | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.102); catalogued as COSV99675247; called by muse, mutect2, varscan2
- SLC38A5 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100476383, COSV58333402; called by muse, mutect2, varscan2
- SLC6A16 | c.1735G>A p.V579I | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs374195315; called by muse, mutect2, varscan2
- SPAG17 | c.5699T>A p.L1900Q | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); catalogued as COSV100308358; called by muse, mutect2, varscan2
- SPATA31D1 | c.4165G>T p.G1389C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs113456427, COSV61193159; called by muse, mutect2, varscan2
- SPATA31E1 | c.1042C>A p.H348N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV100350102; called by muse, mutect2, varscan2
- SPNS3 | c.731G>A p.R244K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as COSV61069604; called by muse, mutect2, varscan2
- SPTAN1 | c.611G>T p.R204I | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100823352; called by muse, mutect2, varscan2
- SSH1 | c.598G>C p.G200R | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV100425388, COSV58460638; called by muse, mutect2, varscan2
- ST14 | c.2074C>T p.R692C | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53836621; called by muse, mutect2, varscan2
- STK39 | c.1377-1G>A p.X459_splice | Splice Site (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100596349; called by muse, mutect2, varscan2
- TADA3 | c.703A>G p.K235E | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.164); catalogued as COSV100112937; called by muse, mutect2, varscan2
- TAT | c.200C>A p.P67Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100587561; called by muse, mutect2, varscan2
- TBC1D19 | c.1012G>T p.A338S | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); catalogued as rs1252831912, COSV53521860; called by muse, mutect2, varscan2
- TBX20 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as COSV101282357, COSV68784287; called by muse, mutect2, varscan2
- TMOD3 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.92); catalogued as rs1219422128; called by muse, mutect2
- TMTC1 | c.1267C>A p.L423I (on ENST00000539277 / NM_001193451.2; = p.L315I on NM_175861.3) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99759079; called by muse, mutect2, varscan2
- TOP2A | c.887G>A p.R296K | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV101396095; called by muse, mutect2, varscan2
- TP53BP1 | c.5732-1G>A p.X1911_splice | Splice Site (SNP) | VAF 12/90 reads (13%) | catalogued as COSV53021412, COSV99538912; called by muse, mutect2
- TRAF1 | c.692G>T p.S231I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV100875123; called by muse, mutect2, varscan2
- TRHDE | c.1759G>T p.V587L | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99669744; called by muse, mutect2, varscan2
- TSC22D2 | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100721197; called by muse, mutect2, varscan2
- USP19 | c.3166G>T p.G1056C | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100025938, COSV60045478; called by muse, mutect2, varscan2
- USP7 | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100784060; called by muse, mutect2, varscan2
- VGLL3 | c.683G>C p.R228P | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.232); catalogued as COSV101051877, COSV101051922; called by muse, varscan2
- VGLL3 | c.682C>G p.R228G | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.088); catalogued as COSV101051878, COSV67352465; called by muse, varscan2
- VGLL3 | c.681G>T p.M227I | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV67352593, COSV67353011; called by muse, varscan2
- VPS50 | c.988A>G p.K330E | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100004628; called by muse, mutect2, varscan2
- WRAP73 | c.1014T>G p.F338L | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99573198; called by muse, mutect2, varscan2
- XRCC5 | c.2024G>A p.W675* | Nonsense Mutation (SNP) | VAF 24/43 reads (56%) | catalogued as COSV101079403; called by muse, mutect2, varscan2
- ZNF155 | c.938A>T p.E313V | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99525559; called by muse, mutect2, varscan2
- ZNF208 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.162); catalogued as COSV101236902; called by muse, mutect2, varscan2
- ZNF3 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 33/111 reads (30%) | catalogued as COSV99447145; called by muse, mutect2, varscan2
- ZNF536 | c.2879G>A p.S960N | Missense Mutation (SNP) | VAF 87/258 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100834887; called by muse, mutect2, varscan2
- ZNF674 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as rs1449956576, COSV101345029; called by muse, mutect2, varscan2
- ZNF780B | c.1319C>G p.S440C | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99665444; called by muse, mutect2, varscan2
- ADAMTS20 | c.4988_4989del p.W1663* | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel
- BIRC6 | c.12649C>T p.L4217F | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); called by muse, mutect2
- DHX9 | c.2740G>C p.D914H | Missense Mutation (SNP) | VAF 8/250 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- IGKV1-9 | c.9G>T p.M3I | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- KARS1 | c.1321G>T p.A441S | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.481); called by muse, mutect2
- MTOR | c.277dup p.L93Pfs*27 | Frame Shift Ins (INS) | VAF 6/20 reads (30%) | called by mutect2, pindel, varscan2
- PCDHGB1 | c.1567_1568del p.A523Lfs*30 | Frame Shift Del (DEL) | VAF 27/98 reads (28%) | called by pindel, varscan2
- TJP1 | c.4196C>T p.S1399F | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.429); called by muse, mutect2
- TNN | c.3760-5_3779delinsTGGTAGGGGGGGAACTGGGAGCCTT p.X1254_splice | Splice Site (ONP) | VAF 4/49 reads (8%) | called by mutect2*, pindel, varscan2*
- ADCY9 | c.3360G>A p.L1120= | Silent (SNP) | VAF 47/119 reads (39%) | catalogued as COSV99569584; called by muse, mutect2, varscan2
- CNTNAP2 | c.399C>T p.I133= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV100672052, COSV62258622; called by muse, mutect2, varscan2
- COL21A1 | c.2310G>T p.G770= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99777907; called by muse, mutect2, varscan2
- ERN1 | c.1845G>T p.L615= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV101458407; called by muse, mutect2, varscan2
- GTF3C1 | c.3231G>A p.E1077= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs766647048, COSV100649112, COSV62242617; called by muse, mutect2, varscan2
- HOXD3 | c.420C>A p.A140= | Silent (SNP) | VAF 38/169 reads (22%) | catalogued as COSV99979994; called by muse, mutect2, varscan2
- HUWE1 | c.10377C>G p.L3459= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV99471163; called by muse, mutect2, varscan2
- HUWE1 | c.5298G>T p.L1766= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as rs1228677048, COSV99471165; called by muse, mutect2, varscan2
- IFNB1 | c.237C>G p.T79= | Silent (SNP) | VAF 65/189 reads (34%) | catalogued as COSV101207782, COSV66525413; called by muse, mutect2, varscan2
- LALBA | c.27G>A p.L9= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV99974355; called by muse, mutect2, varscan2
- LAMA2 | c.8259A>T p.A2753= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV101370244; called by muse, mutect2, varscan2
- MBOAT7 | c.687C>T p.A229= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs772114260; called by muse, mutect2
- NFE2L1 | c.1266C>G p.L422= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as COSV100671436; called by muse, mutect2, varscan2
- OR11L1 | c.258G>C p.L86= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100869397, COSV100869405; called by muse, mutect2, varscan2
- OR4A15 | c.609G>C p.A203= | Silent (SNP) | VAF 46/133 reads (35%) | catalogued as COSV100123917; called by muse, mutect2, varscan2
- OR6C3 | c.90C>T p.I30= | Silent (SNP) | VAF 41/142 reads (29%) | catalogued as COSV65571374; called by muse, mutect2, varscan2
- PAQR8 | c.999C>T p.C333= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs1193362378, COSV100658415; called by muse, mutect2, varscan2
- PCDHB14 | c.93A>G p.A31= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV99505662; called by muse, mutect2, varscan2
- PCNX3 | c.2943C>A p.V981= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100856147; called by muse, mutect2, varscan2
- PCNX3 | c.3034C>T p.L1012= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100856148; called by muse, mutect2, varscan2
- PCNX3 | c.3144C>G p.V1048= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100856151; called by muse, mutect2, varscan2
- PDE4DIP | c.5346C>T p.N1782= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV100517653; called by muse, mutect2, varscan2
- PLD5 | c.1170C>T p.P390= (on ENST00000442594; = p.P328= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/199 reads (13%) | catalogued as COSV59160130; called by muse, mutect2, varscan2
- RAPH1 | c.2823A>G p.P941= | Silent (SNP) | VAF 48/97 reads (49%) | catalogued as COSV55587218, COSV99863539; called by muse, mutect2, varscan2
- RPGRIP1L | c.1804C>A p.R602= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV100046009, COSV50903640; called by muse, mutect2, varscan2
- SIMC1 | c.240A>T p.T80= (on ENST00000443967 / NM_001308196.1; = p.T99= on NM_001308195.2) | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV100365316; called by muse, mutect2, varscan2
- SMC2 | c.2661T>A p.T887= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV99658629; called by muse, mutect2, varscan2
- TDP1 | c.945G>A p.S315= | Silent (SNP) | VAF 47/181 reads (26%) | catalogued as rs1231168955, COSV59642505; called by muse, mutect2, varscan2
- TECRL | c.951A>T p.T317= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV101168621; called by muse, mutect2, varscan2
- TENM3 | c.1299G>T p.R433= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs1278908879, COSV101304958; called by muse, mutect2, varscan2
- TM4SF20 | c.237C>T p.N79= | Silent (SNP) | VAF 302/615 reads (49%) | catalogued as COSV100459998; called by muse, mutect2, varscan2
- TSPYL6 | c.978T>G p.T326= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV100336394; called by muse, mutect2
- XKR7 | c.1719G>T p.L573= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV101629241; called by muse, mutect2, varscan2
- ZMYND11 | c.1392G>A p.Q464= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV100556016; called by muse, mutect2, varscan2
- ZNF3 | c.513C>T p.S171= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as rs746947731, COSV99447146; called by muse, mutect2, varscan2
- AIFM1 | c.249+1173A>T | Intron (SNP) | VAF 41/148 reads (28%) | catalogued as COSV99780865; called by muse, mutect2, varscan2
- DPF3 | c.871+2959C>T | Intron (SNP) | VAF 17/61 reads (28%) | catalogued as rs762501809, COSV100818449; called by muse, mutect2, varscan2
- FBLN1 | c.186-2445G>T | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99410232; called by muse, mutect2, varscan2
- IL2RA | c.-1G>A | 5'UTR (SNP) | VAF 23/71 reads (32%) | catalogued as rs1397484733, COSV99906572; called by muse, mutect2, varscan2
- KIF1B | c.2115+6785G>T | Intron (SNP) | VAF 46/114 reads (40%) | catalogued as COSV99822797; called by muse, mutect2, varscan2
- MAGEC3 | c.1124-230C>T | Intron (SNP) | VAF 8/162 reads (5%) | catalogued as COSV100025061, COSV100025510; called by muse, mutect2
- MIR325 | n.63G>T | RNA (SNP) | VAF 22/96 reads (23%) | called by muse, mutect2, varscan2
- MIR325 | n.62G>T | RNA (SNP) | VAF 22/98 reads (22%) | called by muse, mutect2, varscan2
- MORF4 | n.637C>A | RNA (SNP) | VAF 76/272 reads (28%) | catalogued as rs1203954308; called by muse, mutect2, varscan2
